Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0LX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0LX-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: UTERUS AND CERVIX, 220 GRAMS, WITH BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- A. MODERATELY DIFFERENTIATED ENDOMETRIOID ADENOCARCINOMA OF THE ENDOMETRIUM WITH SQUAMOUS DIFFERENTIATION INVOLVING ALMOST 100% OF THE ENDOMETRIAL CAVITY (ANTERIOR WALL MASS MEASURED - 6.5 X 5.3 CM AND POSTERIOR WALL MEASURED- 7.5 X 3.0 CM).
- B. ENDOMETRIOID CARCINOMA PENETRATES UP TO 90% OF THE MYOMETRIAL UTERINE WALL.
- B. ENDOMETRIOID ADENOCARCINOMA ARISING IN A BACKGROUND OF COMPLEX AND SIMPLE ENDOMETRIAL HYPERPLASIA.
- C. ANGIOLYMPHATIC INVASION IDENTIFIED.
- D. INTRAMURAL LEIOMYOMA, 2.2 CM MAXIMUM DIAMETER WITH DEGENERATIVE CHANGES.
- E. UTERINE CERVIX -CHRONIC CYSTIC CERVICITIS AND SQUAMOUS METAPLASIA FREE OF TUMOR.
- F. TUBO-OVARIAN ADHESION.
- G. LEFT FALLOPIAN TUBE WITH PARATUBAL CYST AND WALTHARD RESTS.
- H. LEFT OVARY WITH FOCI OF HEMOSIDERIN LADEN MACROPHAGES, ENDOMETRIOSIS, PHYSIOLOGIC CHANGES AND FOCAL MICROCALCIFICATIONS.
- I. RIGHT FALLOPIAN TUBE.
- J. RIGHT OVARY WITH EPITHELIAL INCLUSION, MICROCALCIFICATIONS AND PHYSIOLOGICAL CHANGES.

PART 2: LEFT PELVIC LYMPH NODES -

SEVEN (7) LEFT PELVIC LYMPH NODES, FREE OF TUMOR (0/7).

1CD-0-3

PART 3: LEFT COMMON NODES -

FOUR (4) LEFT COMMON LYMPH NODES, FREE OF TUMOR (0/4).

adeno carcinoma, endometrioid, NOS

8380/3

PART 4: RIGHT PELVIC LYMPH NODES -

FOUR (4) RIGHT PELVIC LYMPH NODES, FREE OF TUMOR (0/4).

Site: endometrium C54.1

lu 5/3/11

PART 5: RIGHT PERIAORTIC LYMPH NODES -

THREE (3) RIGHT PERIAORTIC LYMPH NODES, FREE OF TUMOR (0/3).

PART 6: LEFT PERIAORTIC LYMPH NODES -

FOUR (4) LEFT PERIAORTIC LYMPH NODES, FREE OF TUMOR (0/4).

CASE SYNOPSIS.

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Moderately differentiated (FIGO 2)

ARCHITECTURAL GRADE:

Poorly differentiated

NUCLEAR GRADE:

Grade 2

TUMOR SIZE:

Maximum dimension: 7.5 mm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 100 %, Posterior endomyometrium: 100 %

DEPTH OF INVASION:

Greater than or equal to 1/2 thickness of myometrium

MARGINS OF RESECTION:

Vaginal margin is negative for tumor

ANGIOLYMPHATIC INVASION:

Yes

PRE-NEOPLASTIC CONDITIONS:

Simple endometrial hyperplasia with atypia, Complex endometrial hyperplasia with atypia

OTHER:

Endometrial polyp, Leiomyoma

MITOTIC RATE:

Mitotic rate: 22 / 10 HPF

LYMPH NODES POSITIVE:

Number of lymph nodes positive:: 0

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 2

EXTRANODAL EXTENSION:

No

DISTANT METASTASES (Excludes metastases to vagina, pelvic serosa, and adnexa. Includes lymph nodes other than regional lymph nodes.):

Absent

T STAGE, PATHOLOGIC:

pT1b

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

Not applicable

FIGO STAGE:

IB

RESIDUAL TUMOR:

RX

Source: NCI Genomic Data Commons file 3582513c-0819-4690-8ca8-e0fcad1953ce (TCGA-BG-A0LX.4306E592-FA36-4AB9-BF84-7232CC599A64.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).